CCDI case PBBMXY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/5d28688d-1665-4bcb-b843-9a87e1ad6c24

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 0.6 years (225 days).

Biospecimens (3 samples)
- Sample 0DCX8U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DCXBA, 0DD0A8 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
